Gene-level copy-number profile of tumor specimen CUPP-B4ZC-TTM1-A from CCG case CUPP-B4ZC, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, metastatic; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 71.7 years (26,183 days).
Specimen CUPP-B4ZC-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d9f1da8-765a-42b7-9e98-36aee6c116b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4ZC-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,794 have no estimate.
https://portal.gdc.cancer.gov/files/e8c74ec2-da90-4b47-910d-5a28a02ae568

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 290; copy number 1: 6,805; copy number 2: 48,975; copy number 3: 2,274; copy number 4: 336; copy number 5: 102; copy number 6: 39; copy number 7: 3; copy number 8: 2; copy number 9: 1; copy number 14: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 290 genes in 97 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,505,532, 3 genes: PLCH2, AL139246.1, AL139246.4.
- chr1:2,528,745–2,569,888, 5 genes: HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2.
- chr1:2,590,639–2,636,620, 2 genes (within-gene range 0–14): MMEL1, MMEL1-AS1.
- chr1:3,069,168–3,438,621, 7 genes: PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1.
- chr1:3,487,246–3,611,508, 3 genes (within-gene range 0–2): AL512413.1, MEGF6, MIR551A.
- chr1:116,372,668–116,502,634, 8 genes (within-gene range 0–1): ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2.
- chr1:143,784,376–143,825,837, 4 genes: AC239800.3, LINC02591, RNU1-143P, AC239798.1.
- chr1:228,393,673–228,416,861, 5 genes (within-gene range 0–2): TRIM11, AL670729.1, MIR6742, AL139288.1, TRIM17.
- chr4:1,345,691–1,406,442, 4 genes (within-gene range 0–1): UVSSA, AC078852.2, AC078852.1, NKX1-1.
- chr7:135,853–164,972, 3 genes: AC093627.5, AC093627.4, AC093627.7.
- chr7:155,067,034–155,087,392, 3 genes: HTR5A-AS1, HTR5A, AC093726.3.
- chr9:136,327,476–136,410,614, 5 genes (within-gene range 0–1): GPSM1, DNLZ, CARD9, SNAPC4, ENTR1.
- chr9:136,440,096–136,617,181, 8 genes: SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451.
- chr9:136,658,856–136,687,457, 3 genes (within-gene range 0–11): EGFL7, MIR126, AGPAT2.
- chr10:48,976,554–49,018,897, 3 genes (within-gene range 0–2): AC060234.2, AC060234.1, MIR4294.
- chr10:118,004,916–118,046,941, 2 genes (within-gene range 0–1): RAB11FIP2, AC022395.1.
- chr10:132,433,733–132,518,367, 3 genes: AL451069.3, LINC02870, AL451069.1.
- chr10:132,943,967–132,965,289, 2 genes: LINC01166, LINC01167.
- chr10:133,575,122–133,626,795, 2 genes: OR6L1P, FRG2B.
- chr14:22,422,371–22,483,069, 19 genes (within-gene range 0–2): TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr14:22,495,913–22,518,871, 19 genes (within-gene range 0–2): TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27, TRAJ26, TRAJ25.
- chr14:101,041,363–101,044,283, 3 genes: MIR300, MIR1185-1, MIR1185-2.
- chr14:105,093,609–105,100,131, 2 genes: LINC02298, AL512356.4.
- chr14:105,140,982–105,181,323, 4 genes (within-gene range 0–4): JAG2, MIR6765, AL512356.1, NUDT14.
- chr16:649,311–705,808, 11 genes (within-gene range 0–1): WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16.
- chr16:853,634–981,318, 5 genes (within-gene range 0–1): LMF1, AL031716.1, AL008727.1, LMF1-AS1, AC009041.3.
- chr16:1,148,224–1,280,544, 14 genes: AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P, AC120498.7, AC120498.5.
- chr16:1,431,078–1,475,084, 7 genes (within-gene range 0–3): PERCC1, CCDC154, AL032819.2, CLCN7, AL031600.3, AL031600.1, AL031600.2.
- chr16:1,576,716–1,610,328, 3 genes (within-gene range 0–1): Z97633.1, AL133297.1, AL133297.2.
- chr16:88,856,220–89,052,966, 8 genes (within-gene range 0–2): TRAPPC2L, PABPN1L, CBFA2T3, AC092384.2, AC092384.3, AC092384.1, AC135782.2, AC135782.1.
- chr17:41,008,521–41,047,316, 6 genes: KRTAP3-1, KRTAP1-5, KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1.
- chr17:81,125,276–81,125,955, 3 genes (within-gene range 0–1): MIR657, MIR3065, MIR338.
- chr17:81,303,771–81,345,966, 3 genes: LINC00482, TMEM105, AC027601.5.
- chr17:81,375,144–81,390,319, 3 genes: AC110285.1, AC110285.5, AC110285.2.
- chr17:83,079,609–83,106,910, 3 genes: METRNL, AC130371.2, AC144831.1.
- chr20:62,550,453–62,570,764, 3 genes (within-gene range 0–1): MIR1-1HG, MIR1-1, MIR133A2.
- chr20:62,596,732–62,635,862, 3 genes: BX640514.2, AL450469.2, AL450469.1.
- chr20:62,872,250–63,085,071, 9 genes: ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056.
- chr20:63,195,429–63,472,677, 15 genes (within-gene range 0–8): YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1.
- chr21:45,376,191–45,404,369, 3 genes: MTCO1P3, BX322559.1, BX322562.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 149 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,586,491–2,591,469, 1 gene, copy number 14 (within-gene range 0–14): PRXL2B.
- chr1:8,318,114–8,344,167, 2 genes, copy number 5 (within-gene range 5–11): SLC45A1, Y_RNA.
- chr1:9,942,923–9,985,501, 6 genes, copy number 5–6 (within-gene range 3–6): AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1.
- chr1:51,995,740–52,055,191, 6 genes, copy number 5: RN7SL290P, TXNDC12, AL445685.3, KTI12, AL445685.1, TXNDC12-AS1.
- chr1:143,652,050–143,699,619, 2 genes, copy number 5–16: RNU1-114P, RNVU1-17.
- chr1:143,729,407–143,729,570, 1 gene, copy number 5: RNVU1-18.
- chr1:143,766,540–143,769,083, 1 gene, copy number 6: FAM91A3P.
- chr1:143,846,097–143,846,504, 1 gene, copy number 8: AC239798.2.
- chr1:143,929,994–144,068,350, 3 genes, copy number 5: RPL22P5, FAM72C, SRGAP2D.
- chr1:144,523,860–144,593,652, 4 genes, copy number 5: RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F.
- chr1:151,131,685–151,249,536, 7 genes, copy number 5: SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A.
- chr1:155,335,268–155,563,162, 6 genes, copy number 5 (within-gene range 4–5): ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4.
- chr1:160,876,540–160,885,180, 1 gene, copy number 7: ITLN1.
- chr1:224,208,741–224,213,625, 1 gene, copy number 6: AC092809.2.
- chr2:61,575,774–61,589,663, 2 genes, copy number 6: AC016727.2, RPS29P10.
- chr2:229,922,302–230,013,119, 4 genes, copy number 5 (within-gene range 2–7): FBXO36, RNU6-964P, FBXO36-IT1, RNU6-1027P.
- chr5:69,280,175–69,470,136, 9 genes, copy number 5: CCDC125, CFL1P5, CHCHD2P2, NDUFB9P1, AK6, TAF9, RAD17, MARVELD2, RPS27P14.
- chr5:134,601,149–134,855,133, 8 genes, copy number 5–6 (within-gene range 2–6): SAR1B, RNU6-1311P, SEC24A, RNU6-1164P, RNU6-757P, CAMLG, DDX46, AC010301.1.
- chr5:157,085,832–157,142,869, 2 genes, copy number 5 (within-gene range 4–5): HAVCR2, AC011377.1.
- chr6:35,781,019–35,797,344, 2 genes, copy number 5: CLPSL1, CLPS.
- chr6:73,362,658–73,417,566, 6 genes, copy number 5–6 (within-gene range 4–6): KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43.
- chr7:73,834,590–73,865,890, 2 genes, copy number 5: METTL27, TMEM270.
- chr8:94,590,115–94,594,601, 2 genes, copy number 5–6: AC023632.3, AC023632.4.
- chr8:97,772,313–97,853,013, 3 genes, copy number 5: Y_RNA, LAPTM4B, AP003357.1.
- chr11:46,677,080–46,705,912, 2 genes, copy number 5: ARHGAP1, ZNF408.
- chr12:14,192,002–14,221,297, 2 genes, copy number 5: AC135001.1, AC092112.1.
- chr12:31,589,923–31,616,439, 4 genes, copy number 6 (within-gene range 3–6): DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3.
- chr12:111,642,146–111,842,902, 7 genes, copy number 5–6 (within-gene range 3–6): BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1.
- chr12:121,604,902–121,672,631, 3 genes, copy number 5: RNU6-1004P, ORAI1, MORN3.
- chr13:19,818,121–19,863,649, 3 genes, copy number 5: ST6GALNAC4P1, ZMYM5, AL355001.1.
- chr14:18,634,955–18,637,421, 2 genes, copy number 6 (within-gene range 2–6): CR383656.1, CR383656.12.
- chr15:72,407,778–72,475,168, 3 genes, copy number 5 (within-gene range 2–5): TMEM202-AS1, PHBP20, AC079322.1.
- chr16:46,702,282–46,831,180, 3 genes, copy number 6: MYLK3, AC007225.1, C16orf87.
- chr16:46,884,362–46,978,983, 3 genes, copy number 5: GPT2, DNAJA2, AC018845.3.
- chr16:70,251,983–70,289,707, 2 genes, copy number 6 (within-gene range 3–6): AARS1, RN7SL279P.
- chr17:30,831,966–30,895,869, 4 genes, copy number 6 (within-gene range 4–6): ATAD5, AC130324.2, RNU6-298P, AC130324.1.
- chr17:67,774,591–67,785,293, 2 genes, copy number 5: RPSAP67, RPL17P41.
- chr19:1,259,384–1,279,244, 3 genes, copy number 6: CIRBP, CIRBP-AS1, FAM174C.
- chr20:35,520,852–35,529,652, 2 genes, copy number 5: FO393401.1, C20orf173.
- chr20:36,870,099–36,894,235, 2 genes, copy number 5–6 (within-gene range 3–6): RN7SL156P, TLDC2.

Autosomal genes at a single copy (total copy number 1): 4,700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
